Somatic mutation profile of tumor specimen 0DSI8G from CCDI case PBCHZW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Dermatofibrosarcoma protuberans, NOS; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 2.4 years (864 days).
Specimen 0DSI8G: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dda862a4-b67d-44a9-b411-8e22dd1df3f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSI85 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/908b5611-37cb-4525-89ed-bac2231cf283

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR2Y1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 33/387 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs776793152, COSV57136597; called by muse, mutect2
- RELB | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 21/512 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as COSV99672690; called by muse, mutect2
- EWSR1 | c.1012+65A>T | Intron (SNP) | VAF 9/208 reads (4%) | called by muse, mutect2
